Gene-level copy-number profile of specimen HCM-CSHL-0765-C56-85P from HCMI case HCM-CSHL-0765-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary.
Specimen HCM-CSHL-0765-C56-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cfa0e399-cc09-495a-832f-59199d915672.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0765-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/e8928b42-3b17-4664-81fa-b52f72ad4c76

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 684; copy number 2: 9,028; copy number 3: 20,092; copy number 4: 17,312; copy number 5: 6,032; copy number 6: 2,249; copy number 7: 2,094; copy number 8: 631; copy number 9: 125; copy number 10: 83; copy number 11: 10; copy number 12: 2; copy number 15: 14; copy number 16: 1; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–3): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr15:21,990,074–22,126,434, 9 genes (within-gene range 0–1): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P.
- chr22:18,846,811–18,861,049, 2 genes: AC008132.1, BCRP7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,399 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,487,246–3,487,627, 1 gene, copy number 10: AL512413.1.
- chr1:35,557,473–43,389,808, 235 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr1:118,614,333–120,467,739, 48 genes, copy number 9–10: PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2.
- chr1:143,419,625–151,953,985, 342 genes, copy number 7–8 (broad region; genes not listed).
- chr8:97,772,313–145,066,685, 737 genes, copy number 7–15 (broad region; genes not listed).
- chr9:136,440,096–136,780,218, 26 genes, copy number 7: SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3.
- chr11:69,048,932–69,136,316, 1 gene, copy number 8 (within-gene range 4–8): TPCN2.
- chr11:69,083,176–69,083,258, 1 gene, copy number 8: MIR3164.
- chr12:131,828,393–131,851,783, 1 gene, copy number 10: MMP17.
- chr14:104,681,146–104,722,535, 1 gene, copy number 11 (within-gene range 3–11): INF2.
- chr14:105,472,962–105,492,267, 3 genes, copy number 8–16 (within-gene range 5–16): CRIP2, CRIP1, AL928654.3.
- chr14:105,526,583–105,530,202, 1 gene, copy number 10: TMEM121.
- chr16:366,969–387,113, 2 genes, copy number 10–11 (within-gene range 3–11): MRPL28, PGAP6.
- chr16:2,088,708–2,135,898, 2 genes, copy number 7 (within-gene range 6–19): PKD1, MIR1225.
- chr16:2,106,669–2,154,165, 7 genes, copy number 7 (within-gene range 7–19): MIR6511B1, AC009065.6, AC009065.3, Y_RNA, MIR4516, MIR3180-5, RAB26.
- chr17:81,303,771–81,309,248, 1 gene, copy number 10: LINC00482.
- chr18:15,003,975–15,006,352, 1 gene, copy number 10: AP005242.2.
- chr19:1,259,384–1,279,244, 3 genes, copy number 9–15: CIRBP, CIRBP-AS1, FAM174C.
- chr19:3,607,247–3,613,930, 1 gene, copy number 11 (within-gene range 6–11): CACTIN-AS1.
- chr19:14,903,232–15,058,293, 7 genes, copy number 7–8: OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14.
- chr19:17,075,781–17,214,537, 1 gene, copy number 7 (within-gene range 4–7): MYO9B.
- chr19:17,152,588–17,433,724, 26 genes, copy number 7: AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3.
- chr19:19,063,994–20,127,076, 57 genes, copy number 8 (within-gene range 3–8): SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B, BORCS8, RFXANK, NR2C2AP, NCAN, RNU6-1028P, AC138430.1, HAPLN4, AC138430.2, TM6SF2, SUGP1, MAU2, GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP, ATP13A1, ZNF101, AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10, AC011477.2, ZNF93, AC007204.1, AC007204.2, ZNF682, AC006539.2, AC006539.3, BNIP3P13, ZNF90, AC006539.1, AC011447.5.
- chr19:20,125,044–20,125,484, 1 gene, copy number 8 (within-gene range 3–8): AC011447.1.
- chr20:87,250–8,968,360, 213 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:33,490,075–56,460,387, 528 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:61,953,469–62,065,810, 1 gene, copy number 8 (within-gene range 6–8): TAF4.
- chr20:62,037,429–64,072,347, 122 genes, copy number 7–19 (broad region; genes not listed).
- chr21:7,744,962–8,680,934, 28 genes, copy number 8: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.
- chr22:20,148,416–20,151,055, 1 gene, copy number 8: CCDC188.

Autosomal genes at a single copy (total copy number 1): 372. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
